Gene-level copy-number profile of tumor specimen TCGA-DX-A6YR-01A from TCGA case TCGA-DX-A6YR, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 75.1 years (27,434 days).
Specimen TCGA-DX-A6YR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.e5d7e2bc-630c-4eb0-90cf-137dd1d8d0cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6YR-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9cae5741-76b8-479b-93dc-32d561667248

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 2,309; copy number 2: 19,421; copy number 3: 22,902; copy number 4: 9,440; copy number 5: 4,527; copy number 6: 955; copy number 7: 145; copy number 8: 15; copy number 10: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6YR-01A-33D-A350-01): tumor purity 0.77, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,493,876–2,728,577, 6 genes (within-gene range 0–2): AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2.
- chr9:20,999,509–22,214,672, 55 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:22,703,516–23,438,700, 1 gene (within-gene range 0–1): AL391117.1.
- chr9:23,291,544–23,293,923, 1 gene: AL357614.1.
- chr9:23,690,104–24,088,051, 6 genes (within-gene range 0–1): ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr10:87,863,625–87,994,695, 4 genes (within-gene range 0–1): PTEN, AC063965.2, RPL11P3, AC063965.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 181 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,080,592–35,093,509, 1 gene, copy number 7: AC099685.1.
- chr8:35,254,344–35,256,605, 1 gene, copy number 7: AC090740.1.
- chr9:75,181,520–75,724,575, 5 genes, copy number 7: Y_RNA, RNU6-1228P, AL158073.1, AL353780.1, OTX2P1.
- chr11:14,262,846–15,930,951, 22 genes, copy number 7: SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682.
- chr11:15,969,533–16,031,515, 2 genes, copy number 7: MIR6073, AC103794.1.
- chr11:24,235,477–26,047,598, 10 genes, copy number 7: LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1.
- chr11:29,159,956–30,017,030, 13 genes, copy number 7: AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4.
- chr13:102,263,046–103,066,417, 21 genes, copy number 7: RPL39P29, FGF14-IT1, AL356266.1, FGF14-AS1, FGF14-AS2, LINC00555, AL158063.1, TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2, SLC10A2.
- chr19:34,675,717–34,926,812, 15 genes, copy number 7: AC020910.6, ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5, AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1.
- chr21:14,961,235–15,065,936, 1 gene, copy number 8 (within-gene range 5–8): NRIP1.
- chr21:14,971,470–16,645,467, 27 genes, copy number 8–10 (within-gene range 3–10): AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2.
- chr21:24,840,550–25,135,247, 8 genes, copy number 8: LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1.
- chr22:22,771,824–23,318,037, 45 genes, copy number 7 (within-gene range 5–7): IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1, IGLJ2, IGLC2, IGLJ3, IGLC3, IGLJ4, IGLC4, IGLJ5, IGLC5, IGLJ6, IGLC6, IGLJ7, IGLC7, AC245054.2, AC245054.1, RSPH14, GNAZ, Metazoa_SRP, U7, RAB36, BCR, BCRP8, RN7SL263P, FBXW4P1.
- chr22:25,742,144–26,383,597, 10 genes, copy number 7 (within-gene range 5–7): MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1.

Autosomal genes at a single copy (total copy number 1): 2,309. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
